Somatic mutation profile of tumor specimen ER-AEK6-TTM1-A (aliquot ER-AEK6-TTM1-A-2-0-D-A598-34) from EXCEPTIONAL_RESPONDERS case ER-AEK6, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Prostate gland; AJCC pathologic stage: Stage I; Age at diagnosis: 66.2 years (24,162 days).
Specimen ER-AEK6-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df9cedbc-d90a-4714-983d-b1057b97c594.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AEK6-NT1-A (Solid Tissue Normal), aliquot ER-AEK6-NT1-A-2-0-D-A598-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e658b5d1-720d-48ff-9b1d-8462d955efc2

The open-access MAF lists 71 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Nonsense Mutation 3, Splice Region 2, Intron 2, Frame Shift Del 2, Splice Site 1, 5'UTR 1, 3'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 14/117 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADTRP | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs763712765; called by muse, mutect2, varscan2
- C1QB | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs908026459; called by muse, mutect2, varscan2
- CARMIL1 | c.4105A>G p.I1369V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs1415139187; called by muse, mutect2, varscan2
- DOLK | c.755C>A p.T252N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.73); catalogued as COSV58279917; called by muse, mutect2, varscan2
- FCGR3A | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 25/473 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs772451890, CM015325; called by muse, mutect2
- HERC1 | c.14063T>C p.I4688T | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1303264501; called by muse, mutect2, varscan2
- ITPRID1 | c.1916C>A p.S639* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV60075596; called by muse, mutect2
- KRTAP4-5 | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV100576830; called by muse, mutect2, varscan2
- LTBP2 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368193784; called by muse, mutect2, varscan2
- PAX1 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1286041632; called by muse, mutect2
- PCLO | c.2236A>G p.K746E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1365955898; called by muse, mutect2, varscan2
- PCNT | c.4477G>A p.E1493K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs141071168; called by muse, mutect2, varscan2
- PTH2R | c.583T>G p.F195V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99782489; called by muse, mutect2
- ADAMTS20 | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ALG10B | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 86/477 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP21 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 28/393 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- BRF1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- CDKAL1 | c.1317A>T p.Q439H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP76 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 42/581 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- CSMD3 | c.7867C>T p.P2623S (on ENST00000297405 / NM_001363185.1; = p.P2519S on NM_052900.3) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DAAM1 | c.1050T>G p.F350L | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- EXOC3 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FABP1 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2
- FANCB | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 130/384 reads (34%) | called by muse, mutect2, varscan2
- FBXO11 | c.2006+5A>G | Splice Region (SNP) | VAF 88/460 reads (19%) | called by muse, mutect2, varscan2
- FKBP3 | c.77T>G p.I26S | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2
- GCC1 | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GGNBP2 | c.1368C>T p.G456= | Splice Region (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- GPR183 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HSP90B1 | c.1331dup p.L444Ffs*12 | Frame Shift Ins (INS) | VAF 10/85 reads (12%) | called by mutect2, varscan2
- IKZF4 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2
- KRTAP4-5 | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2
- LTB | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.494); called by muse, mutect2
- MAP1S | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.106); called by muse, mutect2
- MCF2L2 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- MOCOS | c.1809del p.W603Cfs*3 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- MYOF | c.4415A>G p.Q1472R | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2
- MYT1L | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- PHF20L1 | c.484T>C p.C162R | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PLCB4 | c.3320T>A p.V1107D | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- PLEKHF2 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PRAMEF20 | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- PXDNL | c.4006C>G p.L1336V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAMD13 | c.114-6_124del p.X38_splice (on ENST00000370671; = p.X32_splice on NM_001010971.3) | Splice Site (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel, varscan2
- SCAMP5 | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SGPL1 | c.1636T>A p.L546M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SLC9A9 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); called by muse, mutect2
- STUB1 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAF1L | c.5069_5101del p.L1690_E1701delins* | Nonsense Mutation (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel
- TIMM22 | c.217G>C p.A73P | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- USP6 | c.2334del p.D778Efs*9 | Frame Shift Del (DEL) | VAF 45/216 reads (21%) | called by mutect2, pindel, varscan2
- ZNF486 | c.153C>A p.F51L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- ITSN1 | c.1740G>A p.Q580= | Silent (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- MRAS | c.435G>A p.A145= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs754375420, COSV56670688; called by muse, mutect2, varscan2
- OR51A7 | c.795G>A p.K265= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV63787989; called by muse, mutect2
- POM121L12 | c.426G>A p.A142= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV68692379; called by muse, varscan2
- PRX | c.2283G>A p.P761= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as rs1340076007, COSV52527595; ClinVar: uncertain significance; called by muse, mutect2
- RYR1 | c.7125G>A p.G2375= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, varscan2
- RYR3 | c.10857G>T p.R3619= (on ENST00000389232; = p.R3620= on NM_001036.6) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1170556101; called by muse, mutect2, varscan2
- SAMD12 | c.33T>C p.N11= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- TAGAP | c.1029T>C p.D343= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- TFAP2B | c.678C>G p.T226= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- VWA3B | c.3693C>T p.I1231= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- ZNF268 | c.963A>G p.V321= | Silent (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- ZNF404 | c.1179G>A p.K393= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- IRS1 | c.-871T>A | 5'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- MAST4 | c.643-29110G>A | Intron (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- TRIM66 | c.2396-97_2396-90del | Intron (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- WT1 | chr11:32440114 A>T | 5'Flank (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- ZNF518A | c.*108C>T | 3'UTR (SNP) | VAF 31/112 reads (28%) | catalogued as rs1023363436, COSV100283551; called by muse, mutect2, varscan2
